Somatic mutation profile of tumor specimen ALCH-B48P-TTP1-A (aliquot ALCH-B48P-TTP1-A-5-0-D-A799-36) from ALCHEMIST case ALCH-B48P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,950 days).
Specimen ALCH-B48P-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a6c37a5-08cc-4754-af14-53069c30b750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B48P-NB1-A (Blood Derived Normal), aliquot ALCH-B48P-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf6078ab-5110-4740-9141-abd1891987bf

The open-access MAF lists 202 somatic variants for this specimen: 137 protein-altering or splice-affecting, 38 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 38, Intron 13, Nonsense Mutation 8, Frame Shift Del 4, 5'UTR 3, RNA 3, 3'Flank 3, 5'Flank 3, Splice Region 2, Splice Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 179/408 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50296596, COSV99408076; called by muse, mutect2, varscan2
- NF1 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 146/362 reads (40%) | catalogued as rs753529924, CM076333, COSV62200743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1742T>G p.L581R | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs780481855; called by muse, mutect2
- ACKR1 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 75/209 reads (36%) | catalogued as COSV63672437; called by muse, mutect2, varscan2
- ACTN2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 135/473 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as COSV63973921; called by muse, mutect2, varscan2
- ARV1 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 119/427 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59617501; called by muse, mutect2, varscan2
- BBOX1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as rs751664988; called by muse, mutect2, varscan2
- CCDC102B | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 270/623 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs560614390; called by muse, mutect2, varscan2
- CEP162 | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs753747368; called by muse, mutect2
- CFD | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs759176909; called by muse, varscan2
- DYDC1 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1302176720, COSV64731037, COSV64731844; called by muse, mutect2, varscan2
- FIG4 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs756709973; called by muse, mutect2
- FSIP2 | c.14072G>T p.R4691M | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1157127281; called by muse, mutect2, varscan2
- GABRR2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375811770; called by muse, mutect2, varscan2
- GALE | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 132/783 reads (17%) | catalogued as COSV52526061; called by muse, mutect2, varscan2
- GRM8 | c.1444A>G p.S482G | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1354218152; called by muse, mutect2
- INPP4B | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV53733726; called by muse, mutect2, varscan2
- IRAK2 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367547215; called by muse, mutect2, varscan2
- ITM2A | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV64811204; called by muse, mutect2, varscan2
- KDM7A | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs1277608437, COSV50092643; called by muse, mutect2
- KIR2DL1 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 104/884 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52412855; called by muse, mutect2, varscan2
- LAMA1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 120/878 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101055357; called by muse, varscan2
- LAMB2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.591); catalogued as rs772368832; called by muse, mutect2, varscan2
- MACC1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs768500596; called by muse, mutect2
- METTL15 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 54/455 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as rs141286273; called by muse, mutect2, varscan2
- NPAS4 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as rs923439670; called by muse, mutect2, varscan2
- OR10S1 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164057582; called by muse, mutect2, varscan2
- OR4D5 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100189634; called by muse, mutect2, varscan2
- P2RX1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as rs747273574, COSV56653418; called by muse, mutect2, varscan2
- PAPPA2 | c.2808C>G p.H936Q | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); catalogued as rs776925998; called by muse, mutect2
- PCDH7 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62343509; called by muse, mutect2, varscan2
- PCDHB8 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 178/2740 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.114); catalogued as rs1554281018, COSV50784399; called by muse, mutect2
- PCNX2 | c.1297C>A p.L433M | Missense Mutation (SNP) | VAF 104/346 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV99268890; called by muse, mutect2, varscan2
- PHYHIPL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as rs776627275; called by muse, mutect2, varscan2
- RBMXL2 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1288022591, COSV100182646; called by muse, mutect2, varscan2
- RTL1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs755868800; called by muse, mutect2
- RTP3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as rs1464581294; called by muse, mutect2, varscan2
- SLC4A7 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1340948361; called by muse, mutect2
- SLITRK1 | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 358/813 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65675555, COSV65675616; called by muse, mutect2, varscan2
- SORBS3 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53551836; called by muse, mutect2, varscan2
- SUGCT | c.104T>A p.M35K | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV59358146; called by muse, mutect2, varscan2
- TMEM225 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66694201; called by muse, mutect2, varscan2
- TRBV20-1 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as rs544649528; called by muse, mutect2, varscan2
- ZNF695 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 39/714 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV60585557; called by muse, mutect2
- ABCB1 | c.694T>A p.W232R | Missense Mutation (SNP) | VAF 264/883 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTS19 | c.1627del p.A543Pfs*16 | Frame Shift Del (DEL) | VAF 112/477 reads (23%) | called by mutect2, pindel, varscan2
- APBB1IP | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGAP29 | c.2796A>G p.E932= | Splice Region (SNP) | VAF 20/107 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP35 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ART3 | c.403T>C p.F135L | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATAD2B | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BDP1 | c.3128A>T p.E1043V | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- C16orf78 | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- CABP1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); called by muse, mutect2
- CACNA1C | c.4791C>A p.S1597R | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CCDC51 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2
- CDC42BPA | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CELSR2 | c.5210T>C p.L1737P | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CPS1 | c.2896-2A>T p.X966_splice | Splice Site (SNP) | VAF 104/445 reads (23%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2643A>T p.K881N (on ENST00000402739 / NM_001282597.3; = p.K833N on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX1 | c.1474C>A p.P492T (on ENST00000437600 / NM_181500.4; = p.P494T on NM_001913.5) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2
- DACT1 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 54/659 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDI1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DISP1 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2
- DRD1 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 84/542 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELF2 | c.1079A>T p.N360I (on ENST00000379550 / NM_001331036.2; = p.N300I on NM_006874.4) | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ERBB4 | c.1654T>A p.C552S | Missense Mutation (SNP) | VAF 156/1055 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM120C | c.2558T>C p.F853S | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC7 | c.905A>T p.H302L | Missense Mutation (SNP) | VAF 88/411 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FSIP2 | c.2171C>G p.P724R | Missense Mutation (SNP) | VAF 82/720 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GAB1 | c.749del p.P250Hfs*47 | Frame Shift Del (DEL) | VAF 78/423 reads (18%) | called by mutect2, pindel, varscan2
- GALNT16 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 133/623 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GIGYF2 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 194/808 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, varscan2
- GNAL | c.719A>T p.Y240F (on ENST00000269162 / NM_001142339.3; = p.Y317F on NM_182978.4) | Missense Mutation (SNP) | VAF 86/325 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH2 | c.499A>T p.M167L | Missense Mutation (SNP) | VAF 110/670 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- GRAP2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HOXB3 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HTR4 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 36/711 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGKV1D-12 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 56/1154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- INTS1 | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- KLHL33 | c.1523C>G p.P508R | Missense Mutation (SNP) | VAF 87/398 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMA1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 122/719 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LIPI | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2
- LRRTM4 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MAST3 | c.2612A>G p.D871G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); called by muse, mutect2
- MCMDC2 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MEDAG | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MKRN3 | c.738T>A p.Y246* | Nonsense Mutation (SNP) | VAF 125/252 reads (50%) | called by muse, mutect2, varscan2
- MROH2A | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 110/541 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC12 | c.13332del p.V4446Sfs*201 (on ENST00000379442; = p.V4303Sfs*201 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, varscan2
- MUC5B | c.16312G>T p.D5438Y | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- MUC5B | c.16313A>T p.D5438V | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NEK10 | c.362+1G>C p.X121_splice | Splice Site (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- NLRP4 | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPIPA8 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 200/444 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- OBSCN | c.19078_19096del p.Q6360Cfs*23 | Frame Shift Del (DEL) | VAF 102/436 reads (23%) | called by mutect2, pindel, varscan2
- OLR1 | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- OR5B3 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.074); called by muse, mutect2
- PACS2 | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- PCDHB12 | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 92/519 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCLO | c.4952A>G p.Q1651R | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PFKFB1 | c.886A>T p.I296F | Missense Mutation (SNP) | VAF 60/179 reads (34%) | PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PSEN1 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 162/836 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PURB | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- PZP | c.4142C>A p.A1381D | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RRM2B | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 45/666 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR3 | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 106/266 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SCG5 | c.395A>G p.E132G (on ENST00000300175 / NM_001144757.2; = p.E131G on NM_003020.4) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- SEC14L3 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- SETBP1 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 39/1051 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2
- SLC22A2 | c.1459delinsGG p.R487Gfs*4 | Frame Shift Ins (INS) | VAF 51/396 reads (13%) | called by pindel, varscan2*
- SLC2A13 | c.1319G>T p.S440I | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.374); called by muse, mutect2
- SLC35G1 | c.596T>G p.L199R (on ENST00000427197 / NM_001134658.3; = p.L198R on NM_153226.4) | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMIM19 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMIM19 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTA1 | c.6130C>A p.L2044M | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAC1 | c.208A>T p.K70* | Nonsense Mutation (SNP) | VAF 21/320 reads (7%) | called by muse, mutect2
- TAF7 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 154/936 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX22 | c.933T>A p.F311L | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- TCERG1L | c.1099T>C p.W367R | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TCF4 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TECRL | c.963A>T p.P321= | Splice Region (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- TSBP1 | c.1005G>T p.K335N (on ENST00000617061; = p.K340N on NM_006781.5) | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN19 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TTN | c.80243T>G p.I26748S (on ENST00000591111; = p.I19324S on NM_003319.4) | Missense Mutation (SNP) | VAF 12/147 reads (8%) | PolyPhen benign (0.049); called by muse, mutect2
- UBE3C | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 77/309 reads (25%) | called by muse, varscan2
- UNC5B | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USH2A | c.13451C>T p.T4484I | Missense Mutation (SNP) | VAF 58/786 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.096); called by muse, mutect2
- USP51 | c.706T>C p.C236R | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCP | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 28/982 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VEGFB | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 74/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWF | c.7348G>T p.V2450L | Missense Mutation (SNP) | VAF 148/660 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- XPOT | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2
- ZNF124 | c.410T>G p.F137C (on ENST00000543802 / NM_001297568.1; = p.F75C on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF26 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.018); called by muse, mutect2
- ZNF512B | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF518A | c.2987A>C p.E996A | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- AKT2 | c.675G>T p.L225= | Silent (SNP) | VAF 12/318 reads (4%) | called by muse, mutect2
- ARHGAP23 | c.3291C>T p.F1097= | Silent (SNP) | VAF 132/433 reads (30%) | called by muse, mutect2, varscan2
- ASB5 | c.102C>T p.S34= | Silent (SNP) | VAF 68/315 reads (22%) | called by muse, mutect2, varscan2
- CYP4F8 | c.636C>T p.S212= | Silent (SNP) | VAF 36/339 reads (11%) | called by muse, mutect2, varscan2
- DNAH5 | c.12081T>A p.G4027= | Silent (SNP) | VAF 18/492 reads (4%) | called by muse, mutect2
- DSCAML1 | c.4341C>A p.P1447= (on ENST00000321322; = p.P1387= on NM_020693.4) | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- GALNT1 | c.1350G>A p.E450= | Silent (SNP) | VAF 12/93 reads (13%) | called by muse, varscan2
- GIGYF2 | c.2601G>A p.R867= | Silent (SNP) | VAF 184/724 reads (25%) | called by muse, varscan2
- HLCS | c.921G>A p.L307= | Silent (SNP) | VAF 275/540 reads (51%) | called by muse, mutect2, varscan2
- HMCN1 | c.9252C>T p.N3084= | Silent (SNP) | VAF 81/1368 reads (6%) | catalogued as rs764091385, COSV54878501; called by muse, mutect2
- IL6 | c.72T>A p.A24= | Silent (SNP) | VAF 80/439 reads (18%) | called by muse, mutect2, varscan2
- ITGA1 | c.840A>T p.T280= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- ITIH3 | c.1080C>A p.T360= | Silent (SNP) | VAF 115/241 reads (48%) | called by muse, mutect2, varscan2
- JAK3 | c.2748G>C p.R916= | Silent (SNP) | VAF 120/274 reads (44%) | called by muse, mutect2, varscan2
- KRTAP10-5 | c.735C>T p.S245= | Silent (SNP) | VAF 119/276 reads (43%) | called by muse, mutect2, varscan2
- LENG8 | c.2487G>T p.G829= | Silent (SNP) | VAF 58/261 reads (22%) | called by muse, mutect2, varscan2
- LRRD1 | c.874T>C p.L292= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, varscan2
- MDGA2 | c.2637C>A p.G879= (on ENST00000399232 / NM_001113498.2; = p.G581= on NM_182830.4) | Silent (SNP) | VAF 115/462 reads (25%) | called by muse, mutect2, varscan2
- MYEF2 | c.783G>T p.R261= | Silent (SNP) | VAF 184/578 reads (32%) | called by muse, mutect2, varscan2
- NALCN | c.3915T>C p.C1305= | Silent (SNP) | VAF 68/219 reads (31%) | called by muse, varscan2
- NLGN4X | c.2175G>A p.Q725= | Silent (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- OAZ3 | c.108T>G p.L36= | Silent (SNP) | VAF 55/790 reads (7%) | called by muse, mutect2
- PCDHB4 | c.1311C>A p.T437= | Silent (SNP) | VAF 205/1089 reads (19%) | catalogued as COSV52026722; called by muse, mutect2, varscan2
- PCDHGB3 | c.1335C>T p.V445= | Silent (SNP) | VAF 164/525 reads (31%) | called by muse, mutect2, varscan2
- PPIL4 | c.954G>C p.S318= | Silent (SNP) | VAF 150/376 reads (40%) | catalogued as COSV99481989; called by muse, mutect2, varscan2
- PRAMEF11 | c.135C>A p.A45= | Silent (SNP) | VAF 78/1076 reads (7%) | called by muse, mutect2
- RTL1 | c.1677C>T p.Y559= | Silent (SNP) | VAF 36/142 reads (25%) | called by muse, mutect2, varscan2
- SAMD7 | c.768G>A p.E256= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs1027968069; called by muse, mutect2, varscan2
- SCN2A | c.1749A>G p.R583= | Silent (SNP) | VAF 192/588 reads (33%) | called by muse, mutect2, varscan2
- SERPINA5 | c.657A>G p.Q219= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs764850106; called by muse, mutect2
- STXBP2 | c.1620C>T p.G540= | Silent (SNP) | VAF 101/209 reads (48%) | catalogued as rs374131788; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TAS2R41 | c.264C>T p.H88= | Silent (SNP) | VAF 34/524 reads (6%) | called by muse, mutect2
- TRUB1 | c.939A>G p.A313= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- TTN | c.37782G>A p.V12594= (on ENST00000591111; = p.V5170= on NM_003319.4) | Silent (SNP) | VAF 29/845 reads (3%) | catalogued as COSV60244399; called by muse, mutect2
- TUBG1 | c.1224C>T p.F408= | Silent (SNP) | VAF 173/429 reads (40%) | called by muse, mutect2, varscan2
- VCPIP1 | c.1395C>A p.R465= | Silent (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- WNT4 | c.376C>A p.R126= | Silent (SNP) | VAF 289/797 reads (36%) | catalogued as rs779763651, COSV51604952; called by muse, mutect2, varscan2
- ZC3H4 | c.2862A>C p.S954= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs769665594; called by muse, mutect2
- AC136759.1 | n.841T>A | RNA (SNP) | VAF 71/199 reads (36%) | called by muse, mutect2, varscan2
- AIPL1 | c.-1C>A | 5'UTR (SNP) | VAF 190/439 reads (43%) | catalogued as COSV100006161; called by muse, mutect2, varscan2
- CCNQP1 | n.435C>T | RNA (SNP) | VAF 30/404 reads (7%) | catalogued as rs367808812; called by muse, mutect2
- CFAP65 | c.542+32C>T | Intron (SNP) | VAF 48/808 reads (6%) | called by muse, mutect2
- CTNNA2 | c.1057-79598A>C | Intron (SNP) | VAF 32/446 reads (7%) | called by muse, mutect2
- FABP5P3 | chr7:152446161 T>C | 3'Flank (SNP) | VAF 84/539 reads (16%) | called by muse, mutect2, varscan2
- FAM98B | chr15:38484580 G>A | 3'Flank (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- FRG2KP | chr16:31569234 G>T | 5'Flank (SNP) | VAF 57/705 reads (8%) | called by muse, mutect2
- H2BC15 | c.377+2573T>A | Intron (SNP) | VAF 26/584 reads (4%) | called by muse, mutect2
- HBA1 | c.301-24C>G | Intron (SNP) | VAF 46/515 reads (9%) | catalogued as rs2698755, COSV99285451; called by muse, mutect2
- IFI27L1 | c.28+700G>A | Intron (SNP) | VAF 30/336 reads (9%) | called by muse, mutect2
- KNOP1P1 | n.377T>C | RNA (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-7525G>T | Intron (SNP) | VAF 39/133 reads (29%) | called by muse, mutect2, varscan2
- LRPAP1 | chr4:3500741 G>A | 3'Flank (SNP) | VAF 82/315 reads (26%) | catalogued as rs546206365; called by muse, mutect2, varscan2
- MIR124-2 | chr8:64377519 A>T | 5'Flank (SNP) | VAF 98/758 reads (13%) | called by muse, mutect2, varscan2
- MSH3 | c.*29T>C | 3'UTR (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- NEU4 | c.-4+144G>T | Intron (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53479G>A | Intron (SNP) | VAF 55/269 reads (20%) | catalogued as rs756276075; called by muse, mutect2, varscan2
- PEG10 | c.*805A>C | 3'UTR (SNP) | VAF 106/358 reads (30%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.235+27G>T | Intron (SNP) | VAF 38/515 reads (7%) | called by muse, mutect2
- RBBP4 | c.-51G>T | 5'UTR (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- RNU6-784P | chr4:70705042 G>C | 5'Flank (SNP) | VAF 3/14 reads (21%) | catalogued as rs949832442; called by muse, mutect2
- ST14 | c.635-11C>T | Intron (SNP) | VAF 55/287 reads (19%) | called by muse, mutect2, varscan2
- SUZ12 | c.-33G>T | 5'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23543G>A | Intron (SNP) | VAF 89/305 reads (29%) | catalogued as rs1350526667; called by muse, mutect2, varscan2
- UNC93B1 | c.96+67G>C | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- ZNF280D | c.2214-15T>G | Intron (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
